Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFY, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFY-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile: -

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; nonseminoma (EC 100%); diameter 2.5 cm; tumor confined to testis; angio-invasion present; no invasion of rete testis.

Date of procurement (= date of orchidectomy)

pathologist

professor of pathology

ICD-O-3 NOS
Carcinoma, embryonal
9870/3
Site @ Testis NOS
C62.9
W
3/7/14

Source: NCI Genomic Data Commons file b8aefc16-2532-4cd0-ad26-3f71d1f253d7 (TCGA-2G-AAFY.9B0991EC-7FD0-432A-8929-1C43C6657C58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).